Somatic mutation profile of tumor specimen HCM-CSHL-0802-C67-01A (aliquot HCM-CSHL-0802-C67-01A-11D-A88G-36) from HCMI case HCM-CSHL-0802-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3.
Specimen HCM-CSHL-0802-C67-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5e61b10-7fdf-4a71-9efd-ec51c9b8259b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0802-C67-10A (Blood Derived Normal), aliquot HCM-CSHL-0802-C67-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/820431f4-580d-4494-b0bd-8b45eca48564

The open-access MAF lists 579 somatic variants for this specimen: 382 protein-altering or splice-affecting, 175 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 347, Silent 175, Nonsense Mutation 25, Intron 10, 5'Flank 4, 3'UTR 4, 5'UTR 3, Frame Shift Ins 2, Splice Region 2, Splice Site 2, Frame Shift Del 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 54/540 reads (10%) | catalogued as rs1333555322, COSV52290439; ClinVar: pathogenic; called by muse, mutect2
- SCN1A | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121917929, CM066998, CM066999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 129/511 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.47086C>T p.R15696* (on ENST00000591111; = p.R8272* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 33/504 reads (7%) | catalogued as rs1343120755, COSV100624672, COSV59893970; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA12 | c.131G>C p.R44P | Missense Mutation (SNP) | VAF 25/399 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV99792281; called by muse, mutect2
- ADAMTS10 | c.2003C>T p.T668M | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782568976; called by muse, mutect2
- ADAMTS12 | c.2810C>G p.S937C | Missense Mutation (SNP) | VAF 74/848 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as COSV61254513; called by muse, mutect2
- ADGRG6 | c.1693A>G p.T565A | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs746431638; called by muse, mutect2, varscan2
- ADORA3 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 42/432 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs766923748, COSV53986544; called by muse, mutect2
- AHCYL1 | c.1247G>T p.W416L | Missense Mutation (SNP) | VAF 51/574 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV100779697; called by muse, mutect2
- ALPI | c.773C>A p.A258E | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.013); catalogued as rs780997860; called by muse, mutect2, varscan2
- APTX | c.846C>G p.F282L | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779509889; called by muse, mutect2, varscan2
- ARHGAP15 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 64/489 reads (13%) | catalogued as rs763082124, COSV54517013; called by muse, mutect2, varscan2
- ARSG | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.084); catalogued as rs570153124, COSV71592939; called by muse, mutect2
- ATP6V1G2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 77/833 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.532); catalogued as rs141644284; called by muse, mutect2
- BTN3A3 | c.1675C>A p.H559N | Missense Mutation (SNP) | VAF 48/604 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99764877; called by muse, mutect2
- BTNL8 | c.1377C>G p.I459M | Missense Mutation (SNP) | VAF 61/613 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99180472; called by muse, mutect2
- C4BPA | c.1579G>T p.G527W | Missense Mutation (SNP) | VAF 58/454 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100891093, COSV65536185; called by muse, mutect2, varscan2
- C5orf34 | c.1069G>T p.G357W | Missense Mutation (SNP) | VAF 47/625 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100175579; called by muse, mutect2
- CALR | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 71/500 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100331220; called by muse, mutect2, varscan2
- CATSPER1 | c.804C>G p.H268Q | Missense Mutation (SNP) | VAF 47/412 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1330304355; called by muse, mutect2, varscan2
- CHST8 | c.1094C>A p.P365Q | Missense Mutation (SNP) | VAF 48/758 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749617284; called by muse, mutect2
- CHTF18 | c.2413C>A p.Q805K | Missense Mutation (SNP) | VAF 51/455 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50210206; called by muse, mutect2, varscan2
- COCH | c.1452C>A p.F484L (on ENST00000216361 / NM_001347720.1; = p.F419L on NM_004086.3) | Missense Mutation (SNP) | VAF 52/417 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV53550535; called by mutect2, varscan2
- COL4A4 | c.2762G>C p.G921A | Missense Mutation (SNP) | VAF 65/517 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61634894; called by muse, mutect2, varscan2
- CYP4F12 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 29/560 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1446468400; called by muse, mutect2
- DLGAP2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 88/814 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs747744035, COSV70103813; called by muse, mutect2, varscan2
- DNHD1 | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); catalogued as rs145615971; called by muse, mutect2, varscan2
- DOP1B | c.849G>C p.Q283H | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.986); catalogued as rs754298902, COSV67695449; called by muse, mutect2, varscan2
- DYNC1H1 | c.9403C>A p.Q3135K | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.029); catalogued as rs1049866462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFL7 | c.253C>G p.R85G | Missense Mutation (SNP) | VAF 78/557 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.277); catalogued as COSV100452072, COSV58247170; called by muse, mutect2, varscan2
- ENPP4 | c.569C>A p.A190E | Missense Mutation (SNP) | VAF 38/581 reads (7%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.614); catalogued as rs1386499550; called by muse, mutect2
- EXOSC7 | c.781C>A p.R261S | Missense Mutation (SNP) | VAF 42/357 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as COSV99651931; called by muse, mutect2, varscan2
- FYTTD1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 35/686 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV54083039; called by muse, mutect2
- GFUS | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 42/574 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99643706; called by muse, mutect2
- GNA14 | c.63C>G p.I21M | Missense Mutation (SNP) | VAF 59/507 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs370899063; called by muse, mutect2, varscan2
- GNB1L | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 88/751 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755525483, COSV61548327; called by muse, mutect2, varscan2
- GNE | c.116G>A p.R39Q (on ENST00000396594 / NM_001128227.3; = p.R8Q on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/457 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs763057654, COSV64951324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR137 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 44/317 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1419767506, COSV100464176; called by muse, mutect2, varscan2
- HES4 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 69/537 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1202631718, COSV59242824; called by muse, mutect2, varscan2
- HOXD9 | c.683C>A p.A228E | Missense Mutation (SNP) | VAF 70/654 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as COSV50896251; called by muse, mutect2, varscan2
- IBA57 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 47/401 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100812773, COSV64510995, COSV64511185; called by muse, mutect2, varscan2
- IFT122 | c.1381G>A p.G461R (on ENST00000348417 / NM_052989.3; = p.G402R on NM_018262.4) | Missense Mutation (SNP) | VAF 53/465 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs368786226; called by muse, mutect2, varscan2
- IRGC | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 135/552 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99746442; called by muse, mutect2, varscan2
- KCNH2 | c.3371C>A p.A1124D | Missense Mutation (SNP) | VAF 66/634 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.034); catalogued as COSV51214378; called by muse, varscan2
- KIAA1109 | c.13048C>G p.P4350A | Missense Mutation (SNP) | VAF 60/590 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99152363; called by muse, mutect2, varscan2
- LAMA1 | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 95/486 reads (20%) | catalogued as COSV101056912; called by muse, mutect2, varscan2
- LAPTM5 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as rs1392006173; called by muse, mutect2, varscan2
- LDHC | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV99772534; called by muse, mutect2, varscan2
- MGA | c.2840C>G p.S947* | Nonsense Mutation (SNP) | VAF 43/361 reads (12%) | catalogued as COSV54948648; called by muse, mutect2, varscan2
- MKLN1 | c.2005C>G p.H669D | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV61759959; called by muse, mutect2, varscan2
- MMP28 | c.1499G>T p.R500L | Missense Mutation (SNP) | VAF 62/509 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs146307755; called by muse, mutect2, varscan2
- MROH1 | c.501C>A p.S167R | Missense Mutation (SNP) | VAF 52/409 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV58192725; called by muse, mutect2, varscan2
- MST1R | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 62/513 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs767728277, COSV56572230; called by muse, mutect2, varscan2
- MTNR1B | c.492C>G p.I164M | Missense Mutation (SNP) | VAF 69/625 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.515); catalogued as COSV99925345; called by muse, mutect2, varscan2
- MYBPC1 | c.178T>C p.F60L (on ENST00000550270 / NM_206820.2; = p.F85L on NM_002465.4) | Missense Mutation (SNP) | VAF 15/412 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1482178435; called by muse, mutect2
- MYO1F | c.2990C>A p.A997E | Missense Mutation (SNP) | VAF 44/498 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV57797643; called by muse, mutect2
- NCAM2 | c.2116G>T p.G706C | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs748488774, COSV99520257; called by mutect2, varscan2
- NEK1 | c.1976A>G p.H659R | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs944312566; called by muse, mutect2
- NF2 | c.863C>G p.S288* | Nonsense Mutation (SNP) | VAF 81/314 reads (26%) | catalogued as COSV58523216; called by muse, mutect2, varscan2
- OR10H3 | c.496C>A p.H166N | Missense Mutation (SNP) | VAF 42/401 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV59944027; called by muse, mutect2, varscan2
- OSMR | c.1775G>T p.R592M | Missense Mutation (SNP) | VAF 34/521 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.766); catalogued as COSV57081646; called by muse, mutect2
- OXR1 | c.826G>C p.E276Q (on ENST00000442977 / NM_001198532.1; = p.E275Q on NM_018002.3) | Missense Mutation (SNP) | VAF 28/466 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1563726061, COSV56328530; called by muse, mutect2
- PADI2 | c.828G>T p.M276I | Missense Mutation (SNP) | VAF 58/325 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100971046; called by muse, mutect2, varscan2
- PAQR9 | c.912C>A p.F304L | Missense Mutation (SNP) | VAF 53/489 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100503959; called by muse, mutect2, varscan2
- PEG3 | c.3537C>A p.F1179L | Missense Mutation (SNP) | VAF 53/623 reads (9%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as COSV55634145, COSV99689718; called by muse, mutect2
- PHRF1 | c.1597G>T p.A533S (on ENST00000264555 / NM_001286581.2; = p.A532S on NM_020901.4) | Missense Mutation (SNP) | VAF 70/431 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759707741; called by muse, mutect2, varscan2
- PIFO | c.575G>T p.*192Lext*18 | Nonstop Mutation (SNP) | VAF 40/483 reads (8%) | catalogued as COSV63863780; called by muse, mutect2
- PLCE1 | c.2711G>C p.S904T | Missense Mutation (SNP) | VAF 27/558 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV53365859; called by muse, mutect2
- PLPP4 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 47/496 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs748975790, COSV64826844; called by muse, mutect2, varscan2
- PLPPR4 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 50/484 reads (10%) | catalogued as COSV64568536; called by muse, mutect2, varscan2
- PLXND1 | c.5068C>T p.H1690Y | Missense Mutation (SNP) | VAF 203/633 reads (32%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.958); catalogued as COSV60719868; called by muse, mutect2, varscan2
- POLQ | c.6862G>A p.G2288S | Missense Mutation (SNP) | VAF 85/321 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs771739818; called by muse, mutect2, varscan2
- POLR2F | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 80/576 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV61005929; called by muse, varscan2
- POM121 | c.2081C>T p.S694F (on ENST00000434423; = p.S429F on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/570 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.401); catalogued as COSV99989166; called by muse, varscan2
- PTK2 | c.2725A>G p.I909V | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.926); catalogued as rs1009418037; called by muse, mutect2
- PTPRC | c.1118A>G p.Y373C | Missense Mutation (SNP) | VAF 98/330 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs771923388; called by muse, mutect2, varscan2
- PTPRD | c.3968G>A p.R1323H | Missense Mutation (SNP) | VAF 55/447 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as rs1172700321; called by muse, mutect2, varscan2
- PTPRS | c.5756G>C p.R1919P | Missense Mutation (SNP) | VAF 38/385 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53634020; called by muse, mutect2, varscan2
- QRFPR | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 42/376 reads (11%) | catalogued as COSV57676811; called by muse, mutect2, varscan2
- RAD17 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV99281430; called by mutect2, varscan2
- RASEF | c.1174C>G p.H392D | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs769817954; called by muse, mutect2, varscan2
- RNF121 | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 51/406 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99474923; called by muse, mutect2, varscan2
- RNF26 | c.1001G>T p.R334I | Missense Mutation (SNP) | VAF 67/467 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV104410200; called by muse, mutect2, varscan2
- RYR2 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 128/456 reads (28%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.833); catalogued as rs1023176208, COSV63718941; called by muse, mutect2, varscan2
- SMTNL2 | c.673G>A p.G225R (on ENST00000389313 / NM_001114974.2; = p.G81R on NM_198501.3) | Missense Mutation (SNP) | VAF 22/724 reads (3%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.896); catalogued as rs1328972841; called by muse, mutect2
- SMYD1 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 123/444 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV70224851; called by muse, mutect2, varscan2
- SOGA1 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 54/482 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.502); catalogued as rs747200639; called by muse, mutect2, varscan2
- SOX14 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 54/690 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1004449220; called by muse, mutect2
- SOX17 | c.1001C>A p.S334* | Nonsense Mutation (SNP) | VAF 116/900 reads (13%) | catalogued as COSV52024098; called by muse, varscan2
- SPG7 | c.1527C>A p.F509L (on ENST00000268704; = p.F516L on NM_003119.4) | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV99245635; called by muse, mutect2, varscan2
- STOM | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 60/455 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763192503; called by muse, mutect2, varscan2
- TBC1D8 | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 71/721 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.791); catalogued as rs768495351; called by muse, mutect2
- TEK | c.1444C>G p.L482V | Missense Mutation (SNP) | VAF 71/558 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as rs1275357194; called by muse, mutect2, varscan2
- TSPAN7 | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 52/255 reads (20%) | catalogued as COSV54534402; called by muse, mutect2, varscan2
- UBR4 | c.11756C>A p.A3919E | Missense Mutation (SNP) | VAF 75/424 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.105); catalogued as COSV64392932; called by muse, mutect2, varscan2
- WWC2 | c.2948G>A p.R983H | Missense Mutation (SNP) | VAF 64/484 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs748036038, COSV67858453; called by muse, mutect2, varscan2
- ZNF219 | c.1384C>A p.H462N | Missense Mutation (SNP) | VAF 79/683 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1052466086; called by muse, mutect2, varscan2
- ZNF683 | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 60/477 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV62874738; called by muse, mutect2, varscan2
- AANAT | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 42/372 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- ABCD3 | c.1900G>C p.E634Q | Missense Mutation (SNP) | VAF 29/422 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.08); called by muse, mutect2
- ABHD1 | c.41C>A p.A14E | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, mutect2
- ABHD14A-ACY1 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 51/402 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC007998.2 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 30/503 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.095); called by muse, mutect2
- ACAD11 | c.2305C>A p.L769M | Missense Mutation (SNP) | VAF 44/446 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACAP2 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACO1 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 66/597 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACSM4 | c.1222G>T p.G408C | Missense Mutation (SNP) | VAF 31/387 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); called by muse, mutect2
- ADAM33 | c.320C>G p.A107G | Missense Mutation (SNP) | VAF 23/699 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.253); called by muse, mutect2
- ADAMTSL4 | c.2218G>T p.G740C | Missense Mutation (SNP) | VAF 67/664 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY7 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 55/510 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKFY1 | c.3265C>A p.Q1089K (on ENST00000341657 / NM_001330063.2; = p.Q1090K on NM_016376.5) | Missense Mutation (SNP) | VAF 43/347 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ANKIB1 | c.2363C>A p.P788Q | Missense Mutation (SNP) | VAF 49/531 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.331); called by muse, mutect2
- AP002748.5 | c.1565C>A p.P522Q | Missense Mutation (SNP) | VAF 74/470 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOC3 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 78/653 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- APOL1 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 68/594 reads (11%) | called by muse, varscan2
- ARHGAP23 | c.698C>A p.P233Q | Missense Mutation (SNP) | VAF 134/2354 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.043); called by muse, mutect2
- ARHGAP23 | c.1426del p.R476Gfs*16 | Frame Shift Del (DEL) | VAF 1379/2558 reads (54%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.3797C>G p.T1266S (on ENST00000310343 / NM_001378025.1; = p.T917S on NM_014715.4) | Missense Mutation (SNP) | VAF 62/457 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARSL | c.1184G>T p.W395L | Missense Mutation (SNP) | VAF 92/417 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARVCF | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 59/473 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ATP11A | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 74/438 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ATP1A3 | c.2535C>A p.D845E (on ENST00000545399 / NM_001256214.2; = p.D832E on NM_152296.5) | Missense Mutation (SNP) | VAF 44/430 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2
- ATP8B3 | c.2551C>A p.Q851K | Missense Mutation (SNP) | VAF 64/706 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.056); called by muse, mutect2
- ATRIP | c.1933dup p.R645Kfs*21 (on ENST00000320211 / NM_130384.3; = p.R645Kfs*78 on NM_032166.4) | Frame Shift Ins (INS) | VAF 50/492 reads (10%) | called by mutect2, pindel
- ATRNL1 | c.716G>T p.W239L | Missense Mutation (SNP) | VAF 64/557 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BAHCC1 | c.3847C>A p.H1283N | Missense Mutation (SNP) | VAF 78/625 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BAHCC1 | c.5426C>A p.P1809Q | Missense Mutation (SNP) | VAF 53/430 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- BARHL2 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 66/639 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- BCAM | c.1582C>A p.H528N | Missense Mutation (SNP) | VAF 53/431 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- BMX | c.527C>A p.A176E | Missense Mutation (SNP) | VAF 40/293 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- BNIP5 | c.103C>A p.H35N | Missense Mutation (SNP) | VAF 36/796 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, mutect2
- C16orf91 | c.109C>A p.H37N | Missense Mutation (SNP) | VAF 53/497 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- C17orf75 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2
- C19orf47 | c.4G>T p.V2F | Missense Mutation (SNP) | VAF 37/419 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); called by muse, mutect2
- C2orf16 | c.2779G>T p.G927* | Nonsense Mutation (SNP) | VAF 44/518 reads (8%) | called by muse, mutect2
- C5 | c.3445G>T p.V1149L | Missense Mutation (SNP) | VAF 31/400 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- C6orf226 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 62/570 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- CACNA1E | c.3874A>G p.I1292V | Missense Mutation (SNP) | VAF 30/708 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- CAVIN2 | c.442C>A p.Q148K | Missense Mutation (SNP) | VAF 45/671 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2
- CC2D2B | c.505G>T p.G169* | Nonsense Mutation (SNP) | VAF 63/262 reads (24%) | called by muse, mutect2, varscan2
- CCDC136 | c.2578C>A p.L860M | Missense Mutation (SNP) | VAF 42/448 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC15 | c.1115C>A p.P372Q | Missense Mutation (SNP) | VAF 58/573 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- CCDC178 | c.727C>A p.Q243K | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2
- CCDC191 | c.529A>C p.K177Q | Missense Mutation (SNP) | VAF 39/702 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.049); called by muse, mutect2
- CCDC28A | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 22/280 reads (8%) | called by muse, mutect2
- CCDC81 | c.1060C>T p.L354F (on ENST00000445632 / NM_001156474.2; = p.L264F on NM_021827.4) | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CCDC88B | c.1016G>T p.C339F | Missense Mutation (SNP) | VAF 64/582 reads (11%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCSAP | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 28/700 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2
- CDC42BPG | c.2049C>A p.D683E | Missense Mutation (SNP) | VAF 48/303 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CDCA2 | c.2318C>G p.A773G | Missense Mutation (SNP) | VAF 54/457 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CDH17 | c.1465T>C p.Y489H | Missense Mutation (SNP) | VAF 62/640 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDIP1 | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 69/629 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- CDK12 | c.4174A>C p.T1392P (on ENST00000447079 / NM_016507.4; = p.T1383P on NM_015083.3) | Missense Mutation (SNP) | VAF 71/1731 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- CENATAC | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 44/386 reads (11%) | called by muse, mutect2, varscan2
- CFAP99 | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 25/508 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHDH | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 23/361 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.109); called by muse, mutect2
- CHGB | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 32/642 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2
- CLDN14 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 61/533 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC4M | c.1050-1G>T p.X350_splice | Splice Site (SNP) | VAF 26/256 reads (10%) | called by muse, mutect2
- CLN6 | c.326C>A p.P109Q | Missense Mutation (SNP) | VAF 48/490 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- CLTC | c.2788C>A p.L930I | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- CNTROB | c.1085G>T p.W362L | Missense Mutation (SNP) | VAF 53/401 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- COL12A1 | c.1027A>G p.M343V | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREBRF | c.591G>T p.L197F | Missense Mutation (SNP) | VAF 52/415 reads (13%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- CSMD2 | c.3976C>A p.L1326M | Missense Mutation (SNP) | VAF 68/507 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP1B1 | c.1370C>G p.T457S | Missense Mutation (SNP) | VAF 68/544 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- DAGLA | c.1285C>A p.H429N | Missense Mutation (SNP) | VAF 53/389 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DDX59 | c.1755_1759dup p.K587Rfs*49 | Frame Shift Ins (INS) | VAF 117/467 reads (25%) | called by mutect2, varscan2
- DDX59 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 34/552 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DMRT3 | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 60/758 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- DNAH1 | c.11872G>T p.A3958S | Missense Mutation (SNP) | VAF 40/556 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.373); called by muse, mutect2
- DNAH14 | c.1463G>T p.C488F (on ENST00000445597; = p.C469F on NM_001367479.1) | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- DNM1 | c.1574G>T p.W525L | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK10 | c.2529C>A p.F843L | Missense Mutation (SNP) | VAF 50/379 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DOP1B | c.4627G>T p.V1543F | Missense Mutation (SNP) | VAF 52/506 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.219); called by muse, mutect2
- DPP6 | c.497G>C p.R166T (on ENST00000377770 / NM_001364500.2; = p.R104T on NM_001936.5) | Missense Mutation (SNP) | VAF 30/411 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- DRG2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DSP | c.6384G>T p.Q2128H | Missense Mutation (SNP) | VAF 58/533 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DST | c.10829A>C p.D3610A | Missense Mutation (SNP) | VAF 30/523 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.177); called by muse, mutect2
- DYRK4 | c.346G>T p.G116* | Nonsense Mutation (SNP) | VAF 69/503 reads (14%) | called by muse, mutect2, varscan2
- EDN3 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 78/905 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2
- EIF2B5 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 70/757 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2
- ELAVL3 | c.902G>T p.W301L | Missense Mutation (SNP) | VAF 73/564 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ESRP1 | c.854G>T p.R285M | Missense Mutation (SNP) | VAF 26/472 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EXD2 | c.739G>T p.A247S (on ENST00000312994 / NM_001193362.1; = p.A122S on NM_018199.3) | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAAP20 | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 79/759 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FADS1 | c.1474C>A p.Q492K | Missense Mutation (SNP) | VAF 46/395 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- FAM171A1 | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 47/560 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM189B | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 34/712 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBXW2 | c.1211C>A p.P404Q | Missense Mutation (SNP) | VAF 56/614 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FER1L5 | c.2090G>T p.W697L (on ENST00000623019; = p.W702L on NM_001293083.2) | Missense Mutation (SNP) | VAF 76/618 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FERMT3 | c.521C>A p.A174E | Missense Mutation (SNP) | VAF 47/422 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- FERMT3 | c.1642C>A p.Q548K (on ENST00000279227 / NM_178443.3; = p.Q544K on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/626 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2
- FLG | c.3965C>G p.S1322C | Missense Mutation (SNP) | VAF 42/610 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2
- FOS | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 79/630 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- FOXI3 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 34/298 reads (11%) | called by muse, varscan2
- FOXN1 | c.378C>A p.Y126* | Nonsense Mutation (SNP) | VAF 82/651 reads (13%) | called by muse, mutect2, varscan2
- FYCO1 | c.3496G>A p.A1166T | Missense Mutation (SNP) | VAF 70/516 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- GBGT1 | c.898C>A p.H300N | Missense Mutation (SNP) | VAF 69/433 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GDPD2 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 131/311 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GFPT2 | c.1189G>T p.V397L | Missense Mutation (SNP) | VAF 39/424 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); called by muse, mutect2
- GFRAL | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 38/564 reads (7%) | called by muse, mutect2
- GLCE | c.1765C>A p.L589I | Missense Mutation (SNP) | VAF 54/522 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOT1 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 48/379 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRHL1 | c.867C>A p.S289R | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- GTF2IRD1 | c.1441G>T p.G481W | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- H3C7 | c.74C>G p.A25G | Missense Mutation (SNP) | VAF 76/494 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HCLS1 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 97/357 reads (27%) | called by muse, mutect2, varscan2
- HDAC3 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HINFP | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 44/347 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- HM13 | c.355C>A p.H119N | Missense Mutation (SNP) | VAF 72/670 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HOXA13 | c.889C>A p.Q297K | Missense Mutation (SNP) | VAF 70/580 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- IER5 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 66/708 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IFFO1 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 88/650 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- IGLV1-40 | c.283G>C p.A95P | Missense Mutation (SNP) | VAF 108/530 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- INO80B | c.108C>G p.H36Q | Missense Mutation (SNP) | VAF 32/561 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- JPT1 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KAZALD1 | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 75/659 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNF1 | c.168G>T p.L56F | Missense Mutation (SNP) | VAF 52/764 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.346); called by muse, mutect2
- KCNQ5 | c.2288C>A p.P763Q | Missense Mutation (SNP) | VAF 54/560 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- KIAA1841 | c.1777C>A p.Q593K | Missense Mutation (SNP) | VAF 21/336 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.034); called by muse, mutect2
- KIFC1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 59/892 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.044); called by muse, mutect2
- KIRREL3 | c.1340C>G p.P447R | Missense Mutation (SNP) | VAF 61/488 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLF10 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 20/638 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, mutect2
- KLHL6 | c.1636C>A p.H546N | Missense Mutation (SNP) | VAF 86/635 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KMT2B | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 86/755 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KMT2E | c.3764C>A p.S1255* | Nonsense Mutation (SNP) | VAF 41/390 reads (11%) | called by muse, mutect2, varscan2
- KRT1 | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 108/818 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); called by muse, varscan2
- LAMB4 | c.4471+1G>C p.X1491_splice | Splice Site (SNP) | VAF 19/208 reads (9%) | called by muse, mutect2
- LCT | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 107/409 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRBA | c.4909A>G p.I1637V | Missense Mutation (SNP) | VAF 15/485 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- LRG1 | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 60/530 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); called by mutect2, varscan2
- LRP2 | c.2723G>A p.G908D | Missense Mutation (SNP) | VAF 45/449 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2
- LRP2 | c.2014C>A p.Q672K | Missense Mutation (SNP) | VAF 51/435 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- LRP3 | c.761G>T p.C254F | Missense Mutation (SNP) | VAF 79/670 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LRP4 | c.2149G>T p.G717C | Missense Mutation (SNP) | VAF 62/376 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- LRWD1 | c.1511C>A p.A504E | Missense Mutation (SNP) | VAF 29/399 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- LVRN | c.381C>A p.F127L | Missense Mutation (SNP) | VAF 72/648 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- MAD1L1 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- MAP3K6 | c.3125G>T p.C1042F | Missense Mutation (SNP) | VAF 74/587 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- MCF2L | c.1681C>A p.Q561K (on ENST00000375608; = p.Q529K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/1240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- MEGF8 | c.8038C>A p.Q2680K (on ENST00000251268 / NM_001271938.2; = p.Q2613K on NM_001410.3) | Missense Mutation (SNP) | VAF 45/575 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2
- MIA3 | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 30/516 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.272); called by muse, mutect2
- MLYCD | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 89/726 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MOGS | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 106/338 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MORC4 | c.1199G>T p.W400L | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- MOV10 | c.1610C>A p.A537E | Missense Mutation (SNP) | VAF 27/379 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MPI | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 58/434 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MRPL9 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.253); called by muse, mutect2
- MTUS2 | c.1991C>A p.P664Q | Missense Mutation (SNP) | VAF 77/906 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- MUC12 | c.16073C>A p.P5358Q (on ENST00000379442; = p.P5215Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0.01); called by muse, mutect2
- MUC16 | c.42361C>T p.P14121S | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.99); called by muse, mutect2
- MYH7B | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); called by muse, mutect2
- MYOCD | c.2449C>A p.L817I | Missense Mutation (SNP) | VAF 61/508 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYOD1 | c.535T>C p.Y179H | Missense Mutation (SNP) | VAF 83/742 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCL | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 64/484 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NDNF | c.311C>A p.S104* | Nonsense Mutation (SNP) | VAF 20/362 reads (6%) | called by muse, mutect2
- NDUFS5 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- NEK10 | c.2075C>A p.T692K | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- NEU4 | c.1042G>T p.G348C (on ENST00000391969 / NM_001167602.3; = p.G360C on NM_080741.4) | Missense Mutation (SNP) | VAF 121/808 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NPDC1 | c.34C>A p.H12N | Missense Mutation (SNP) | VAF 42/579 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2
- NPHP4 | c.1546C>A p.Q516K | Missense Mutation (SNP) | VAF 89/410 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NRIP3 | c.108C>G p.I36M | Missense Mutation (SNP) | VAF 76/706 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); called by muse, mutect2
- OR13C4 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 35/588 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2
- OR2AP1 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 36/484 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.566); called by muse, mutect2
- OR2M2 | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 25/680 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2
- OR4A15 | c.648T>G p.Y216* | Nonsense Mutation (SNP) | VAF 58/543 reads (11%) | called by muse, mutect2, varscan2
- OR4E2 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR4K5 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 28/434 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2
- OR5M11 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 38/430 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- OR6Y1 | c.503T>C p.I168T | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- OTOL1 | c.1360G>T p.V454F | Missense Mutation (SNP) | VAF 60/551 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- OTUD6A | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 78/413 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- P2RY2 | c.493C>A p.Q165K | Missense Mutation (SNP) | VAF 88/775 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PATL2 | c.1618G>T p.A540S | Missense Mutation (SNP) | VAF 34/447 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.321); called by muse, mutect2
- PDCD11 | c.5251G>T p.A1751S | Missense Mutation (SNP) | VAF 71/389 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- PDCD6IP | c.566T>G p.L189R | Missense Mutation (SNP) | VAF 50/714 reads (7%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.478); called by muse, mutect2
- PDHB | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 58/600 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- PELI3 | c.590C>A p.P197Q | Missense Mutation (SNP) | VAF 100/619 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PEX7 | c.14G>T p.C5F | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.005); called by muse, mutect2
- PGM2 | c.1570G>T p.G524C | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PI4KB | c.1612C>A p.Q538K (on ENST00000368873 / NM_001369623.1; = p.Q550K on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/390 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PIEZO2 | c.667G>T p.G223W | Missense Mutation (SNP) | VAF 55/501 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PIK3R6 | c.648C>A p.A216= | Splice Region (SNP) | VAF 40/347 reads (12%) | called by muse, mutect2, varscan2
- PLXDC1 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 74/1504 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- PMM1 | c.712C>A p.H238N | Missense Mutation (SNP) | VAF 59/415 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- PNPLA7 | c.2363G>T p.W788L | Missense Mutation (SNP) | VAF 42/483 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- POM121 | c.2820C>A p.F940L (on ENST00000434423; = p.F675L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/539 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- POM121L12 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 113/606 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- PPP1R13B | c.749T>G p.L250R | Missense Mutation (SNP) | VAF 66/525 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- PPP1R1A | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 86/483 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP1R7 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 91/354 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PPP4R1 | c.2728G>T p.V910L (on ENST00000400556 / NM_001042388.3; = p.V893L on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/522 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.05); called by muse, mutect2
- PRKDC | c.1273G>C p.D425H | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTPRS | c.4836G>C p.E1612D | Missense Mutation (SNP) | VAF 50/554 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RAD54L | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 15/488 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- RAG2 | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 59/552 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- RASSF1 | c.262G>C p.D88H (on ENST00000357043 / NM_170714.2; = p.X84_splice on NM_007182.5) | Missense Mutation (SNP) | VAF 46/534 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- RAVER1 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 52/518 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.075); called by muse, mutect2
- RBSN | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 28/552 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RFT1 | c.552G>T p.L184F | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.187); called by muse, mutect2
- RHBDL1 | c.727G>T p.A243S (on ENST00000219551 / NM_001318733.2; = p.A178S on NM_001278720.2) | Missense Mutation (SNP) | VAF 75/563 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- RIMBP3 | c.1423C>A p.Q475K | Missense Mutation (SNP) | VAF 39/764 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2
- RIOK2 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 89/587 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RNF112 | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 71/573 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- RNF212 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 54/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- RNF31 | c.1276G>T p.G426C | Missense Mutation (SNP) | VAF 70/556 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- RPH3A | c.592G>T p.A198S (on ENST00000389385 / NM_001143854.2; = p.A194S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/475 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPN2 | c.1190C>A p.T397K | Missense Mutation (SNP) | VAF 23/437 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.031); called by muse, mutect2
- RRS1 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 32/708 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.497); called by muse, mutect2
- RSAD1 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 80/603 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RTBDN | c.538C>G p.H180D (on ENST00000393233 / NM_001270444.1; = p.H212D on NM_031429.2) | Missense Mutation (SNP) | VAF 64/500 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RUSC2 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 74/600 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SCARF1 | c.2480C>A p.P827Q | Missense Mutation (SNP) | VAF 37/533 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); called by muse, mutect2
- SCUBE1 | c.1252C>A p.Q418K | Missense Mutation (SNP) | VAF 52/428 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- SCYGR5 | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 130/646 reads (20%) | called by muse, mutect2, varscan2
- SDK2 | c.5619C>G p.I1873M | Missense Mutation (SNP) | VAF 81/311 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SI | c.865G>T p.G289* | Nonsense Mutation (SNP) | VAF 25/213 reads (12%) | called by muse, mutect2, varscan2
- SIGLEC1 | c.1741C>A p.H581N | Missense Mutation (SNP) | VAF 76/706 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SIRPD | c.209C>A p.P70Q | Missense Mutation (SNP) | VAF 59/937 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.715); called by muse, mutect2
- SIX1 | c.510C>G p.N170K | Missense Mutation (SNP) | VAF 47/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC18A1 | c.338C>A p.P113Q | Missense Mutation (SNP) | VAF 22/387 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2
- SLC44A3 | c.1855C>A p.L619M (on ENST00000271227 / NM_001114106.3; = p.L571M on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLC5A7 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 26/626 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.01); called by muse, mutect2
- SLC9A3 | c.2436C>A p.D812E | Missense Mutation (SNP) | VAF 61/930 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- SMCO2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 57/379 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SMG5 | c.1923C>A p.S641R | Missense Mutation (SNP) | VAF 49/768 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.316); called by muse, mutect2
- SNRPA | c.115C>A p.Q39K | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.038); called by muse, mutect2
- SNRPB2 | c.315del p.E106Kfs*60 | Frame Shift Del (DEL) | VAF 187/646 reads (29%) | called by mutect2, pindel, varscan2
- SOD2 | c.14C>A p.A5E | Missense Mutation (SNP) | VAF 46/569 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- SORCS1 | c.602G>T p.S201I | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2
- SOX7 | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 52/824 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.365); called by muse, mutect2
- SPATA5 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 36/474 reads (8%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.026); called by muse, mutect2
- SPC24 | c.34C>A p.Q12K | Missense Mutation (SNP) | VAF 60/462 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SRSF11 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 76/845 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); called by muse, mutect2
- STAT3 | c.1666G>T p.G556C | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STRIP1 | c.2275G>T p.A759S | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.462); called by muse, mutect2
- STRN4 | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 38/616 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.339); called by muse, mutect2
- SUZ12 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 24/351 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.138); called by muse, mutect2
- SYNE1 | c.12792C>A p.A4264= (on ENST00000367255 / NM_182961.4; = p.A4193= on NM_033071.3) | Splice Region (SNP) | VAF 31/244 reads (13%) | called by muse, mutect2, varscan2
- SYNJ1 | c.2930T>G p.M977R | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TAB1 | c.1246C>A p.Q416K | Missense Mutation (SNP) | VAF 64/612 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TANC2 | c.4196C>A p.P1399Q | Missense Mutation (SNP) | VAF 53/572 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.043); called by muse, mutect2
- TAS1R3 | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 78/636 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- TBC1D5 | c.2038C>A p.Q680K | Missense Mutation (SNP) | VAF 42/759 reads (6%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.007); called by muse, mutect2
- TCOF1 | c.2686A>T p.I896F (on ENST00000377797 / NM_001135243.1; = p.I819F on NM_000356.4) | Missense Mutation (SNP) | VAF 72/484 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- TECTA | c.3832C>A p.Q1278K | Missense Mutation (SNP) | VAF 65/568 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TIPIN | c.329G>T p.W110L | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TMCO3 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 76/483 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- TMEM86A | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 66/430 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- TNRC6A | c.935C>A p.P312Q | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- TOGARAM2 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 53/510 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOP2A | c.3662C>A p.P1221Q | Missense Mutation (SNP) | VAF 63/435 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPRN | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 37/603 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2
- TRIML2 | c.704G>T p.C235F | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2
- TSGA10IP | c.830T>C p.I277T | Missense Mutation (SNP) | VAF 67/468 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSKS | c.1022G>T p.W341L | Missense Mutation (SNP) | VAF 53/488 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TTC30A | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 135/500 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- TTC39B | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTC5 | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 71/540 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TTI1 | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 61/699 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2
- TUBD1 | c.127C>G p.Q43E | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UACA | c.3376G>T p.G1126C | Missense Mutation (SNP) | VAF 50/437 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- UNKL | c.844C>A p.H282N | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- USP54 | c.4532G>T p.C1511F | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- VTN | c.1415G>T p.C472F | Missense Mutation (SNP) | VAF 25/317 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VWC2 | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 79/747 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- WDR26 | c.1045C>A p.R349S (on ENST00000414423 / NM_001379403.1; = p.R249S on NM_025160.7) | Missense Mutation (SNP) | VAF 38/524 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2
- WDR35 | c.2840C>A p.A947D (on ENST00000345530 / NM_001006657.2; = p.A936D on NM_020779.4) | Missense Mutation (SNP) | VAF 113/335 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZBTB10 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 74/786 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZBTB22 | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 64/902 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.338); called by muse, mutect2
- ZFYVE27 | c.766G>T p.G256C | Missense Mutation (SNP) | VAF 51/516 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.095); called by muse, mutect2
- ZIC2 | c.191C>A p.P64Q | Missense Mutation (SNP) | VAF 146/925 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); called by muse, varscan2
- ZKSCAN4 | c.854G>T p.C285F | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.216); called by muse, mutect2
- ZNF114 | c.1001G>T p.C334F | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF30 | c.1040A>G p.K347R | Missense Mutation (SNP) | VAF 99/483 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- ZNF416 | c.1345C>A p.Q449K | Missense Mutation (SNP) | VAF 73/770 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, mutect2
- ZNF525 | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 25/434 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.113); called by muse, mutect2
- ZNF573 | c.754G>T p.G252W (on ENST00000536220 / NM_001172692.1; = p.G194W on NM_152360.3) | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF705D | c.616G>T p.G206* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- ZNFX1 | c.2660G>T p.W887L | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ADAMTS1 | c.492C>A p.A164= | Silent (SNP) | VAF 83/617 reads (13%) | called by muse, mutect2, varscan2
- ANGPTL6 | c.432C>G p.L144= | Silent (SNP) | VAF 64/525 reads (12%) | called by muse, mutect2, varscan2
- ANKH | c.747C>A p.A249= | Silent (SNP) | VAF 79/910 reads (9%) | called by muse, mutect2
- AP2A2 | c.1575G>T p.L525= | Silent (SNP) | VAF 51/459 reads (11%) | called by muse, mutect2, varscan2
- APEH | c.93G>T p.L31= | Silent (SNP) | VAF 48/774 reads (6%) | called by muse, mutect2
- ARHGEF16 | c.252C>A p.G84= | Silent (SNP) | VAF 69/645 reads (11%) | called by muse, mutect2, varscan2
- ATAD3C | c.900G>T p.L300= | Silent (SNP) | VAF 64/444 reads (14%) | catalogued as rs1295988915; called by muse, mutect2, varscan2
- ATP8B3 | c.1458G>T p.L486= | Silent (SNP) | VAF 60/473 reads (13%) | called by muse, mutect2, varscan2
- ATXN2L | c.1503G>T p.L501= | Silent (SNP) | VAF 37/306 reads (12%) | called by muse, mutect2, varscan2
- B3GALT6 | c.51C>A p.G17= | Silent (SNP) | VAF 55/418 reads (13%) | called by muse, mutect2, varscan2
- BAIAP2 | c.861G>T p.V287= | Silent (SNP) | VAF 49/412 reads (12%) | called by muse, mutect2, varscan2
- BOD1L1 | c.1068G>A p.Q356= | Silent (SNP) | VAF 42/283 reads (15%) | called by muse, mutect2, varscan2
- C1orf226 | c.180C>A p.A60= | Silent (SNP) | VAF 85/764 reads (11%) | called by muse, mutect2, varscan2
- C4orf46 | c.33G>T p.S11= | Silent (SNP) | VAF 87/606 reads (14%) | called by muse, mutect2, varscan2
- CACNA1A | c.3345C>A p.A1115= | Silent (SNP) | VAF 64/638 reads (10%) | called by muse, mutect2, varscan2
- CACNA1G | c.1551C>A p.A517= | Silent (SNP) | VAF 96/824 reads (12%) | called by muse, mutect2, varscan2
- CACNB1 | c.1563C>T p.D521= | Silent (SNP) | VAF 54/1376 reads (4%) | called by muse, mutect2
- CARD11 | c.1005G>A p.E335= | Silent (SNP) | VAF 77/395 reads (19%) | catalogued as COSV101210757; called by muse, mutect2, varscan2
- CCDC39 | c.2676T>G p.S892= | Silent (SNP) | VAF 86/288 reads (30%) | called by muse, mutect2, varscan2
- CCNL1 | c.729G>A p.E243= | Silent (SNP) | VAF 68/553 reads (12%) | called by muse, mutect2, varscan2
- CD276 | c.414G>T p.V138= | Silent (SNP) | VAF 41/434 reads (9%) | called by muse, mutect2, varscan2
- CDH1 | c.714C>T p.N238= | Silent (SNP) | VAF 49/355 reads (14%) | catalogued as rs780297063, COSV55733828; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDK12 | c.192C>A p.G64= | Silent (SNP) | VAF 50/1472 reads (3%) | called by muse, mutect2
- CDK12 | c.4173C>A p.G1391= (on ENST00000447079 / NM_016507.4; = p.G1382= on NM_015083.3) | Silent (SNP) | VAF 70/1734 reads (4%) | called by muse, mutect2
- CDK5RAP2 | c.5184G>T p.L1728= | Silent (SNP) | VAF 41/589 reads (7%) | called by muse, mutect2
- CDKAL1 | c.978C>T p.S326= | Silent (SNP) | VAF 38/526 reads (7%) | catalogued as rs750171067; called by muse, mutect2
- CENPT | c.582C>A p.A194= | Silent (SNP) | VAF 39/374 reads (10%) | called by muse, mutect2, varscan2
- CEP170B | c.4626G>T p.V1542= (on ENST00000453495; = p.V1471= on NM_015005.3) | Silent (SNP) | VAF 100/701 reads (14%) | called by muse, mutect2, varscan2
- CEP250 | c.6555C>A p.A2185= | Silent (SNP) | VAF 39/541 reads (7%) | called by muse, mutect2
- CLCN1 | c.957G>T p.L319= | Silent (SNP) | VAF 45/376 reads (12%) | catalogued as rs746212684; called by muse, mutect2, varscan2
- CLUAP1 | c.519C>A p.A173= | Silent (SNP) | VAF 31/363 reads (9%) | called by muse, mutect2
- COL13A1 | c.1374G>A p.R458= (on ENST00000398978 / NM_001130103.2; = p.R401= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/264 reads (22%) | catalogued as COSV62574691; called by muse, mutect2, varscan2
- COL28A1 | c.342G>T p.L114= | Silent (SNP) | VAF 58/494 reads (12%) | called by muse, mutect2, varscan2
- CSF3 | c.441C>A p.A147= | Silent (SNP) | VAF 56/1272 reads (4%) | called by muse, mutect2
- CSMD3 | c.9642T>A p.T3214= (on ENST00000297405 / NM_001363185.1; = p.T3045= on NM_052900.3) | Silent (SNP) | VAF 64/466 reads (14%) | called by muse, mutect2, varscan2
- CUL9 | c.3546C>A p.A1182= | Silent (SNP) | VAF 42/658 reads (6%) | called by muse, mutect2
- CXCL3 | c.54G>T p.V18= | Silent (SNP) | VAF 35/616 reads (6%) | called by muse, mutect2
- DACH1 | c.1515C>A p.G505= (on ENST00000619232 / NM_001366712.1; = p.G453= on NM_080759.6) | Silent (SNP) | VAF 102/728 reads (14%) | called by muse, varscan2
- DALRD3 | c.1233C>A p.A411= (on ENST00000341949 / NM_001009996.3; = p.A244= on NM_018114.5) | Silent (SNP) | VAF 40/572 reads (7%) | called by muse, mutect2
- DAP3 | c.1194C>G p.L398= | Silent (SNP) | VAF 30/418 reads (7%) | catalogued as rs770022270; called by muse, mutect2
- DCUN1D4 | c.372C>A p.G124= | Silent (SNP) | VAF 52/334 reads (16%) | catalogued as COSV58120907; called by muse, mutect2, varscan2
- DIDO1 | c.5826C>A p.P1942= | Silent (SNP) | VAF 59/590 reads (10%) | called by muse, mutect2
- DNAH5 | c.9468G>T p.V3156= | Silent (SNP) | VAF 67/878 reads (8%) | called by muse, mutect2
- DNMT1 | c.3489G>T p.T1163= | Silent (SNP) | VAF 31/426 reads (7%) | catalogued as COSV61580426; called by muse, mutect2
- DOT1L | c.498G>T p.V166= | Silent (SNP) | VAF 36/302 reads (12%) | called by muse, mutect2, varscan2
- EGFL8 | c.756G>T p.V252= | Silent (SNP) | VAF 63/828 reads (8%) | called by muse, mutect2
- EHMT2 | c.2778G>T p.V926= | Silent (SNP) | VAF 45/341 reads (13%) | called by muse, mutect2, varscan2
- ERVW-1 | c.228C>A p.A76= | Silent (SNP) | VAF 61/501 reads (12%) | called by muse, mutect2, varscan2
- FADS3 | c.1089C>A p.A363= | Silent (SNP) | VAF 74/502 reads (15%) | called by muse, mutect2, varscan2
- FAM102A | c.321G>T p.L107= | Silent (SNP) | VAF 52/305 reads (17%) | called by muse, mutect2, varscan2
- FAM78B | c.129C>A p.R43= | Silent (SNP) | VAF 78/916 reads (9%) | catalogued as COSV57981506; called by muse, mutect2
- FBRSL1 | c.546C>A p.L182= | Silent (SNP) | VAF 102/465 reads (22%) | called by muse, mutect2, varscan2
- FGD5 | c.39C>A p.P13= | Silent (SNP) | VAF 47/423 reads (11%) | catalogued as COSV53250311; called by muse, mutect2, varscan2
- FGF19 | c.537C>T p.L179= | Silent (SNP) | VAF 82/550 reads (15%) | called by muse, mutect2, varscan2
- FMO5 | c.1377G>T p.L459= | Silent (SNP) | VAF 50/456 reads (11%) | called by muse, mutect2, varscan2
- FOXJ1 | c.981G>T p.L327= | Silent (SNP) | VAF 86/677 reads (13%) | called by muse, mutect2, varscan2
- GABRR1 | c.258C>T p.F86= | Silent (SNP) | VAF 30/412 reads (7%) | called by muse, mutect2
- GAS2L2 | c.231G>T p.L77= | Silent (SNP) | VAF 66/558 reads (12%) | called by muse, mutect2, varscan2
- GBF1 | c.3102C>A p.A1034= (on ENST00000369983 / NM_001377137.1; = p.A1033= on NM_004193.3) | Silent (SNP) | VAF 56/399 reads (14%) | called by muse, mutect2, varscan2
- GBGT1 | c.807G>T p.V269= | Silent (SNP) | VAF 59/412 reads (14%) | called by muse, mutect2, varscan2
- GJC3 | c.108G>T p.L36= | Silent (SNP) | VAF 76/834 reads (9%) | called by muse, mutect2
- GPC6 | c.1494C>A p.G498= | Silent (SNP) | VAF 107/556 reads (19%) | called by muse, mutect2, varscan2
- GPR179 | c.807G>T p.V269= (on ENST00000621958; = p.V268= on NM_001004334.4) | Silent (SNP) | VAF 34/969 reads (4%) | called by muse, mutect2
- GRAMD1B | c.180G>T p.L60= | Silent (SNP) | VAF 73/693 reads (11%) | called by muse, mutect2, varscan2
- GRB10 | c.714C>A p.A238= | Silent (SNP) | VAF 34/537 reads (6%) | called by muse, mutect2
- GRHL1 | c.912C>T p.I304= | Silent (SNP) | VAF 36/314 reads (11%) | catalogued as rs761844127; called by muse, mutect2, varscan2
- GRM8 | c.1983C>T p.F661= | Silent (SNP) | VAF 67/593 reads (11%) | called by muse, mutect2, varscan2
- HERC2 | c.775A>C p.R259= | Silent (SNP) | VAF 52/523 reads (10%) | called by muse, mutect2, varscan2
- HGF | c.354C>G p.L118= | Silent (SNP) | VAF 47/349 reads (13%) | catalogued as rs769553578, COSV55956239; called by muse, mutect2, varscan2
- HSPA6 | c.1536G>T p.L512= | Silent (SNP) | VAF 43/642 reads (7%) | called by muse, mutect2
- HTR1A | c.27C>A p.G9= | Silent (SNP) | VAF 47/402 reads (12%) | catalogued as COSV60501462; called by muse, mutect2, varscan2
- IFNA4 | c.423G>T p.L141= | Silent (SNP) | VAF 80/637 reads (13%) | called by muse, mutect2, varscan2
- ILF2 | c.252G>C p.V84= | Silent (SNP) | VAF 36/446 reads (8%) | called by muse, mutect2
- INPP5E | c.792C>A p.R264= | Silent (SNP) | VAF 46/427 reads (11%) | called by muse, mutect2, varscan2
- INPP5E | c.228C>A p.A76= | Silent (SNP) | VAF 111/760 reads (15%) | called by muse, varscan2
- IQCA1L | c.306G>T p.L102= | Silent (SNP) | VAF 70/618 reads (11%) | called by muse, mutect2, varscan2
- KCND1 | c.1584G>A p.L528= | Silent (SNP) | VAF 162/364 reads (45%) | catalogued as rs1557057964, COSV99502080; called by muse, mutect2, varscan2
- KCNK2 | c.621G>T p.V207= (on ENST00000444842 / NM_001017425.3; = p.V192= on NM_014217.4) | Silent (SNP) | VAF 26/484 reads (5%) | called by muse, mutect2
- KCNN1 | c.171C>A p.G57= | Silent (SNP) | VAF 76/629 reads (12%) | called by muse, mutect2, varscan2
- KIAA0895L | c.1014C>A p.L338= | Silent (SNP) | VAF 92/737 reads (12%) | called by muse, mutect2, varscan2
- KIAA1522 | c.2214G>T p.V738= (on ENST00000373480 / NM_001198972.2; = p.V797= on NM_020888.3) | Silent (SNP) | VAF 64/452 reads (14%) | called by mutect2, varscan2
- KIF21B | c.4884C>A p.A1628= (on ENST00000422435 / NM_001252100.2; = p.A1615= on NM_017596.4) | Silent (SNP) | VAF 64/580 reads (11%) | catalogued as COSV59762410; called by muse, mutect2, varscan2
- KLHL34 | c.759C>A p.I253= | Silent (SNP) | VAF 196/542 reads (36%) | catalogued as COSV101069940; called by muse, varscan2
- KRT84 | c.1125C>A p.R375= | Silent (SNP) | VAF 56/441 reads (13%) | called by muse, mutect2, varscan2
- LAMA5 | c.267G>T p.V89= | Silent (SNP) | VAF 73/583 reads (13%) | called by mutect2, varscan2
- LCORL | c.807G>T p.V269= | Silent (SNP) | VAF 66/397 reads (17%) | called by muse, mutect2, varscan2
- LRRC14B | c.414G>T p.L138= | Silent (SNP) | VAF 88/1126 reads (8%) | called by muse, mutect2
- LTN1 | c.4377A>T p.G1459= | Silent (SNP) | VAF 40/341 reads (12%) | called by muse, mutect2, varscan2
- MAGEB16 | c.882G>T p.V294= | Silent (SNP) | VAF 73/451 reads (16%) | called by muse, mutect2, varscan2
- MALL | c.24C>A p.A8= | Silent (SNP) | VAF 24/628 reads (4%) | called by muse, mutect2
- MAPK12 | c.234C>A p.L78= | Silent (SNP) | VAF 55/601 reads (9%) | catalogued as rs1415488299; called by muse, mutect2
- MBD3L2 | c.567G>T p.L189= | Silent (SNP) | VAF 42/1002 reads (4%) | called by muse, mutect2
- MEGF6 | c.2064G>T p.L688= | Silent (SNP) | VAF 58/544 reads (11%) | called by muse, mutect2, varscan2
- METTL24 | c.42G>T p.L14= | Silent (SNP) | VAF 19/479 reads (4%) | catalogued as rs1390474089; called by muse, mutect2
- MEX3B | c.471G>A p.L157= | Silent (SNP) | VAF 103/696 reads (15%) | called by muse, mutect2, varscan2
- MFHAS1 | c.855C>T p.F285= | Silent (SNP) | VAF 35/526 reads (7%) | catalogued as rs746376157; called by muse, mutect2
- MLLT1 | c.1398C>A p.P466= | Silent (SNP) | VAF 35/309 reads (11%) | catalogued as rs1340000320; called by muse, mutect2, varscan2
- MMRN2 | c.2095C>A p.R699= | Silent (SNP) | VAF 74/619 reads (12%) | called by muse, mutect2, varscan2
- MROH2A | c.3534G>T p.L1178= | Silent (SNP) | VAF 33/409 reads (8%) | called by muse, mutect2
- MRPS23 | c.300G>T p.V100= | Silent (SNP) | VAF 47/337 reads (14%) | called by muse, mutect2, varscan2
- MRTFA | c.897C>A p.P299= | Silent (SNP) | VAF 52/622 reads (8%) | called by muse, mutect2
- MUC16 | c.38382G>T p.L12794= | Silent (SNP) | VAF 41/380 reads (11%) | called by muse, mutect2, varscan2
- MUC16 | c.26730C>A p.P8910= | Silent (SNP) | VAF 50/434 reads (12%) | called by muse, mutect2, varscan2
- MUC22 | c.5004G>T p.L1668= | Silent (SNP) | VAF 42/690 reads (6%) | called by muse, mutect2
- MYBPC3 | c.3561G>T p.L1187= | Silent (SNP) | VAF 60/580 reads (10%) | called by muse, mutect2
- MYH14 | c.1707G>T p.V569= | Silent (SNP) | VAF 53/501 reads (11%) | called by muse, varscan2
- MYO18B | c.2880G>C p.A960= | Silent (SNP) | VAF 67/468 reads (14%) | catalogued as COSV100123203, COSV59137936; called by muse, mutect2, varscan2
- MYO5A | c.3123C>A p.L1041= | Silent (SNP) | VAF 53/380 reads (14%) | catalogued as COSV100697701; called by muse, mutect2, varscan2
- NEMP2 | c.54C>A p.A18= | Silent (SNP) | VAF 49/659 reads (7%) | called by muse, mutect2
- NEURL1B | c.369C>A p.V123= | Silent (SNP) | VAF 74/706 reads (10%) | called by muse, mutect2, varscan2
- NID1 | c.3166C>A p.R1056= | Silent (SNP) | VAF 60/664 reads (9%) | called by muse, mutect2
- NLGN1 | c.1137C>G p.L379= | Silent (SNP) | VAF 119/486 reads (24%) | catalogued as COSV100849646; called by muse, mutect2, varscan2
- NRROS | c.1221C>T p.F407= | Silent (SNP) | VAF 57/709 reads (8%) | called by muse, mutect2
- NYNRIN | c.543G>T p.L181= | Silent (SNP) | VAF 97/705 reads (14%) | catalogued as rs759836430; called by muse, mutect2, varscan2
- OLFM1 | c.975G>A p.L325= (on ENST00000371793 / NM_001282611.2; = p.L307= on NM_014279.5) | Silent (SNP) | VAF 87/450 reads (19%) | catalogued as rs1029475081; called by muse, mutect2, varscan2
- OR2Y1 | c.852C>G p.L284= | Silent (SNP) | VAF 105/369 reads (28%) | catalogued as COSV57136232; called by muse, mutect2, varscan2
- OR9K2 | c.792C>A p.S264= (on ENST00000305377; = p.S242= on NM_001005243.1) | Silent (SNP) | VAF 30/476 reads (6%) | catalogued as COSV59532956; called by muse, mutect2
- PCDH11X | c.2913C>T p.T971= | Silent (SNP) | VAF 203/532 reads (38%) | catalogued as COSV100015054; called by muse, mutect2, varscan2
- PCGF2 | c.831C>A p.P277= | Silent (SNP) | VAF 104/2195 reads (5%) | called by muse, mutect2
- PELO | c.1041T>C p.S347= | Silent (SNP) | VAF 58/476 reads (12%) | called by muse, mutect2, varscan2
- PLAAT3 | c.261G>T p.L87= | Silent (SNP) | VAF 83/540 reads (15%) | called by muse, mutect2, varscan2
- PLCH2 | c.489G>T p.L163= | Silent (SNP) | VAF 72/693 reads (10%) | called by muse, mutect2, varscan2
- PLXNA1 | c.3222C>A p.A1074= | Silent (SNP) | VAF 42/700 reads (6%) | called by muse, mutect2
- PLXNA4 | c.5049C>A p.A1683= | Silent (SNP) | VAF 32/434 reads (7%) | called by muse, mutect2
- PROZ | c.894C>T p.G298= | Silent (SNP) | VAF 130/769 reads (17%) | called by muse, mutect2, varscan2
- RANBP3 | c.33C>A p.A11= | Silent (SNP) | VAF 46/400 reads (12%) | catalogued as COSV50380401; called by mutect2, varscan2
- RANBP6 | c.2601A>G p.P867= | Silent (SNP) | VAF 84/398 reads (21%) | catalogued as rs770135556; called by muse, mutect2, varscan2
- RBBP8NL | c.135C>G p.S45= | Silent (SNP) | VAF 47/429 reads (11%) | catalogued as rs754785012; called by muse, mutect2, varscan2
- RECQL4 | c.3597C>A p.A1199= | Silent (SNP) | VAF 50/732 reads (7%) | called by muse, mutect2
- RFXANK | c.693G>T p.V231= | Silent (SNP) | VAF 28/520 reads (5%) | called by muse, mutect2
- RGL2 | c.117G>T p.V39= | Silent (SNP) | VAF 64/521 reads (12%) | called by muse, mutect2, varscan2
- RORA | c.135G>T p.V45= | Silent (SNP) | VAF 65/514 reads (13%) | catalogued as rs911354869; called by muse, mutect2, varscan2
- SCN4A | c.531G>T p.L177= | Silent (SNP) | VAF 41/319 reads (13%) | catalogued as COSV71125675; called by muse, mutect2, varscan2
- SHARPIN | c.537G>T p.L179= | Silent (SNP) | VAF 36/578 reads (6%) | called by muse, mutect2
- SHARPIN | c.183G>T p.L61= | Silent (SNP) | VAF 50/480 reads (10%) | called by muse, mutect2, varscan2
- SLC16A12 | c.405C>A p.A135= | Silent (SNP) | VAF 40/378 reads (11%) | called by muse, mutect2, varscan2
- SLC1A5 | c.714C>A p.A238= | Silent (SNP) | VAF 74/539 reads (14%) | called by muse, mutect2, varscan2
- SLC1A7 | c.102C>A p.G34= | Silent (SNP) | VAF 65/613 reads (11%) | called by muse, mutect2, varscan2
- SLC22A2 | c.168G>T p.V56= | Silent (SNP) | VAF 45/795 reads (6%) | called by muse, mutect2
- SLC25A25 | c.222G>T p.L74= | Silent (SNP) | VAF 62/459 reads (14%) | called by muse, mutect2, varscan2
- SLC26A9 | c.426G>T p.L142= | Silent (SNP) | VAF 31/604 reads (5%) | called by muse, mutect2
- SLC35G6 | c.69C>G p.P23= | Silent (SNP) | VAF 72/646 reads (11%) | called by muse, mutect2, varscan2
- SLITRK5 | c.1644T>G p.V548= | Silent (SNP) | VAF 95/761 reads (12%) | called by muse, mutect2, varscan2
- SMIM32 | c.24C>A p.A8= | Silent (SNP) | VAF 67/520 reads (13%) | called by muse, mutect2, varscan2
- SNED1 | c.1434C>A p.G478= | Silent (SNP) | VAF 43/377 reads (11%) | called by muse, mutect2, varscan2
- SNF8 | c.36C>A p.A12= | Silent (SNP) | VAF 59/392 reads (15%) | called by muse, mutect2, varscan2
- SNX21 | c.438C>A p.S146= | Silent (SNP) | VAF 34/338 reads (10%) | called by muse, mutect2, varscan2
- SOGA1 | c.1632G>T p.L544= | Silent (SNP) | VAF 70/792 reads (9%) | called by muse, mutect2
- SPOUT1 | c.171G>T p.L57= | Silent (SNP) | VAF 36/386 reads (9%) | called by muse, mutect2
- SRBD1 | c.2298C>A p.I766= | Silent (SNP) | VAF 143/517 reads (28%) | called by muse, mutect2, varscan2
- SSTR5 | c.645G>A p.L215= | Silent (SNP) | VAF 177/695 reads (25%) | called by muse, mutect2, varscan2
- SYNE4 | c.501G>C p.R167= | Silent (SNP) | VAF 70/673 reads (10%) | called by muse, mutect2, varscan2
- TACC2 | c.3279G>T p.V1093= | Silent (SNP) | VAF 71/555 reads (13%) | called by muse, mutect2, varscan2
- TAPBPL | c.810G>T p.L270= | Silent (SNP) | VAF 63/473 reads (13%) | called by muse, mutect2, varscan2
- TMEM30B | c.147G>T p.L49= | Silent (SNP) | VAF 62/652 reads (10%) | called by muse, mutect2
- TMPRSS9 | c.1230G>T p.L410= (on ENST00000648592; = p.L376= on NM_182973.2) | Silent (SNP) | VAF 37/354 reads (10%) | called by muse, mutect2
- TNC | c.3432C>T p.I1144= | Silent (SNP) | VAF 85/375 reads (23%) | called by muse, mutect2, varscan2
- TNRC18 | c.5604G>T p.L1868= | Silent (SNP) | VAF 70/575 reads (12%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.4659C>A p.A1553= | Silent (SNP) | VAF 8/214 reads (4%) | called by muse, mutect2
- TOR2A | c.168G>T p.L56= | Silent (SNP) | VAF 66/409 reads (16%) | called by muse, mutect2, varscan2
- TPR | c.807C>A p.A269= | Silent (SNP) | VAF 29/477 reads (6%) | called by muse, mutect2
- TRO | c.3882C>A p.G1294= | Silent (SNP) | VAF 86/411 reads (21%) | called by muse, mutect2, varscan2
- TUFM | c.1305C>A p.G435= | Silent (SNP) | VAF 57/441 reads (13%) | called by muse, mutect2, varscan2
- UGT2B10 | c.1512A>C p.L504= | Silent (SNP) | VAF 66/483 reads (14%) | called by muse, mutect2, varscan2
- UPF3A | c.579C>A p.A193= | Silent (SNP) | VAF 77/502 reads (15%) | called by muse, mutect2, varscan2
- USH1C | c.129G>T p.V43= | Silent (SNP) | VAF 48/356 reads (13%) | catalogued as COSV99142361; called by muse, mutect2, varscan2
- VAX1 | c.849C>G p.S283= | Silent (SNP) | VAF 80/695 reads (12%) | called by muse, mutect2, varscan2
- VN1R1 | c.720C>A p.G240= | Silent (SNP) | VAF 37/382 reads (10%) | called by muse, mutect2, varscan2
- VPS4A | c.645G>T p.L215= | Silent (SNP) | VAF 35/327 reads (11%) | called by muse, mutect2, varscan2
- VWCE | c.27C>G p.A9= | Silent (SNP) | VAF 61/465 reads (13%) | catalogued as rs1371595158; called by muse, mutect2, varscan2
- WHRN | c.141C>T p.T47= | Silent (SNP) | VAF 84/564 reads (15%) | catalogued as rs968697966; called by muse, mutect2, varscan2
- WIZ | c.3177C>A p.A1059= (on ENST00000673675 / NM_001371589.1; = p.A236= on NM_001330395.4) | Silent (SNP) | VAF 66/582 reads (11%) | called by muse, mutect2, varscan2
- ZNF532 | c.1362A>G p.P454= | Silent (SNP) | VAF 73/520 reads (14%) | called by muse, mutect2, varscan2
- ZNF648 | c.381C>A p.P127= | Silent (SNP) | VAF 66/672 reads (10%) | catalogued as COSV60570577; called by muse, mutect2
- ZNF92 | c.1311C>A p.S437= (on ENST00000328747 / NM_152626.4; = p.S368= on NM_007139.4) | Silent (SNP) | VAF 56/490 reads (11%) | called by muse, mutect2, varscan2
- ABI3BP | c.1576+8096C>T | Intron (SNP) | VAF 65/519 reads (13%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73826043 C>T | 5'Flank (SNP) | VAF 38/358 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130914939 G>A | 5'Flank (SNP) | VAF 27/449 reads (6%) | called by muse, mutect2
- C5orf60 | n.944G>T | RNA (SNP) | VAF 37/269 reads (14%) | called by muse, mutect2, varscan2
- CPNE5 | chr6:36843071 G>C | 5'Flank (SNP) | VAF 46/400 reads (12%) | called by muse, mutect2, varscan2
- EEF1D | c.-7-3134C>A | Intron (SNP) | VAF 55/821 reads (7%) | called by muse, mutect2
- FAM219A | c.344+107C>A | Intron (SNP) | VAF 60/460 reads (13%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-2366G>A | Intron (SNP) | VAF 24/565 reads (4%) | called by muse, mutect2
- KCNQ1 | c.1514+16743C>A | Intron (SNP) | VAF 48/360 reads (13%) | called by muse, mutect2, varscan2
- KHDC4 | c.1645+18G>T | Intron (SNP) | VAF 69/697 reads (10%) | called by muse, mutect2
- MAP1A | c.-222G>T | 5'UTR (SNP) | VAF 102/463 reads (22%) | called by muse, mutect2, varscan2
- MAP3K14 | c.1553-78C>T | Intron (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- MIDEAS | c.*338C>A | 3'UTR (SNP) | VAF 53/478 reads (11%) | called by muse, mutect2, varscan2
- MLXIP | c.*49G>T | 3'UTR (SNP) | VAF 44/624 reads (7%) | called by muse, mutect2
- NTMT1 | c.162+81C>A | Intron (SNP) | VAF 40/592 reads (7%) | called by muse, mutect2
- RAF1 | c.-123G>T | 5'UTR (SNP) | VAF 26/374 reads (7%) | called by muse, mutect2
- SNU13 | chr22:41693625 C>A | 5'Flank (SNP) | VAF 69/490 reads (14%) | called by muse, mutect2, varscan2
- STARD3 | c.*35G>C | 3'UTR (SNP) | VAF 111/2557 reads (4%) | called by muse, mutect2
- STARD3 | c.*126C>A | 3'UTR (SNP) | VAF 56/1712 reads (3%) | called by muse, mutect2
- TBX1 | c.1009+496G>T | Intron (SNP) | VAF 62/727 reads (9%) | called by muse, mutect2
- VARS2 | c.-423G>T | 5'UTR (SNP) | VAF 45/641 reads (7%) | called by muse, mutect2
- YIF1A | c.736-29G>T | Intron (SNP) | VAF 98/690 reads (14%) | called by muse, mutect2, varscan2
